Somatic mutation profile of tumor specimen C3N-02715-02 (aliquot CPT0178430006) from CPTAC case C3N-02715, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 36.8 years (13,455 days).
Specimen C3N-02715-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43617e76-e29f-4b68-8122-f1fa1aba05ac.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02715-71 (Blood Derived Normal), aliquot CPT0178540002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0d6bf98-aa05-4c73-a0be-0dedad18b2c7

The open-access MAF lists 20 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF2 | c.395C>A p.P132H | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as COSV60678944; called by muse, mutect2, varscan2
- PRKD3 | c.1698G>C p.E566D | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as COSV52219175; called by muse, mutect2, varscan2
- RGS22 | c.960A>G p.I320M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as rs1201208331; called by muse, mutect2, varscan2
- SLC8B1 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 24/554 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV52530026, COSV99176689; called by muse, mutect2
- CHSY3 | c.1343T>A p.V448E | Missense Mutation (SNP) | VAF 18/217 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.062); called by muse, mutect2
- NCOA5 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 30/470 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR4N2 | c.626T>A p.L209Q | Missense Mutation (SNP) | VAF 100/491 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- PIP5K1A | c.251C>G p.A84G (on ENST00000368888 / NM_001135638.2; = p.A71G on NM_003557.3) | Missense Mutation (SNP) | VAF 89/393 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- PRAMEF8 | c.953T>G p.I318S | Missense Mutation (SNP) | VAF 192/1468 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, varscan2
- PRRT3 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 64/564 reads (11%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RBMXL3 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- SHANK1 | c.1852A>G p.S618G | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT tolerated (0.81); PolyPhen benign (0.007); called by muse, mutect2
- IFT172 | c.3540T>C p.H1180= | Silent (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- SIX4 | c.366G>A p.Q122= | Silent (SNP) | VAF 58/222 reads (26%) | catalogued as COSV53668957; called by muse, mutect2, varscan2
- TENM3 | c.5403C>T p.Y1801= | Silent (SNP) | VAF 64/315 reads (20%) | catalogued as rs758457707, COSV69312058; called by muse, mutect2, varscan2
- WBP1 | c.237A>T p.R79= | Silent (SNP) | VAF 51/388 reads (13%) | called by muse, mutect2, varscan2
- CASK | c.1737+50T>C | Intron (SNP) | VAF 26/308 reads (8%) | called by muse, mutect2
- GALT | c.905-38G>C | Intron (SNP) | VAF 18/166 reads (11%) | called by muse, mutect2, varscan2
- LRR1 | chr14:49598626 G>A | 5'Flank (SNP) | VAF 149/518 reads (29%) | catalogued as rs920677984; called by muse, mutect2, varscan2
- PCSK7 | c.1323+9C>T | Intron (SNP) | VAF 17/400 reads (4%) | called by muse, mutect2
